Surgical pathology report (de-identified scan), TCGA case TCGA-55-A4DG, project TCGA-LUAD (Lung Adenocarcinoma), tissue source site International Genomics Consortium, specimen TCGA-55-A4DG-01A (Primary Tumor).

[page 1 of 3]
SURGICAL PATHOLOGY:

PROCEDURE DATE: RECEIVED DATE: REPORT DATE:

COPY TO: [REDACTED], [REDACTED]

1C203

Adenocarcinoma, NOS

814013

Site: lung upper lobe

C34.1

9-12-12

RD

Pre-Op Diagnosis
Right lung upper lobe nodule
Post-Op Diagnosis
Same as above
Clinical History
Nothing indicated
Gross Description:
Five parts

Container labeled "[REDACTED] 1 - level 9 lymph node" is 1.0 x 0.7 x 0.3 cm irregular fragment of soft gray yellow fibrofatty tissue entirely submitted in a single cassette.

Container labeled "[REDACTED] 2 - level 10 lymph node" are 1.6 x 1.2 x 0.6 cm focally calcified fleshy gray black tissue fragments which are sectioned and entirely submitted in two cassettes.

Container labeled "[REDACTED] 3 - right upper lobe" has a previously partially sectioned recognizable portion of pulmonary parenchyma consistent with right upper lobe. This weighs as received 190 grams and measures 15.0 x 13.4 x 3.9 cm. The margin of resection has a stapled bifurcated tertiary bronchus with an adjacent partially fragmented 0.8 cm fleshy mottled gray black nodule. The pleura is wrinkled mottled gray pink with moderate anthracotic streaking. Noted at the apex slightly posteriorly is a previously sectioned region which exposes a marginal 2.5 x 2.3 x 1.6 cm roughly wedge shaped gray tan firm fibrotic lesion with mottled gray tan fibrotic cut surface. Noted at its nearest point 5.2 cm from the bronchial margin a bronchial connection is grossly identified. This lesion grossly extends to but not through the pleura at the apex. The specimen is received after tissue harvest for genomic study. Within the specimen container are two tissue

[page 2 of 3]
cassettes each labeled immediately adjacent to the lesion are areas of subpleural honeycombing of the pleura which is grossly consistent with paracicatricial emphysema. The remaining parenchyma is spongy tan pink with moderate anthracotic streaking. No significant fluid, honeycombing or additional lesions are identified. Representative sections are submitted labeled as follows: A - shaved bronchial margin and peribronchial nodule; B-F - remaining lesion and surrounding tissue; G - random uninvolved parenchyma.

Container labeled "██████████ 4 - 4R lymph node" are 4.2 x 3.8 x 1.2 cm of gray tan to yellow fibrofatty tissue fragments which scattered poorly defined areas of gray tan to black fleshy tissue. The fleshy tissue areas measure up to 1.0 cm. The specimen is sectioned and the fleshy tissue regions are entirely submitted in two cassettes.

Container labeled "██████████ 5 - level 7 lymph node" is 3.2 x 2.0 x 1.0 cm of fragmented gray yellow to black fleshy and fatty tissue fragments which is sectioned and entirely submitted in three cassettes.

██████████
Microscopic Description:
See diagnosis.

Final Diagnosis

Lymph node, thoracic, level 9, excision:

Negative for malignancy, one small node.

Lymph node, thoracic, level 10, excision:

Reactive hyperplasia; negative for malignancy, several lymph node fragments.

Inactive, dystrophically calcified granulomas are present.

Lung, right upper lobe, lobectomy:

Tumor characteristics:

Histologic type: Adenocarcinoma.

Histologic grade: II (moderately differentiated).

Specimen integrity: Specimen intact; margins can be evaluated.

Tumor site: Posterior apex, subpleural.

Tumor focality: Unifocal.

Tumor size: 2.5 x 2.3 x 1.6 cm.

Visceral pleural invasion: Malignancy extends to, but not through, the visceral pleura.

Lymphovascular space invasion: Not identified.

Tumor extension: Not applicable.

Treatment effect: Not identified.

Surgical margin status:

Tumor distance from bronchial margin: 5.2 cm.

Tumor distance from pleural surface: Less than 1 mm.

Lymph node status:

Total number of lymph nodes received: At least 20 (includes two hilar lymph nodes from

lobectomy specimen, as well as parts 1, 2, 4 and 5 - see comment).

Total number of lymph nodes containing metastatic carcinoma: 0

Other:

The malignancy has a prominent fibrous stroma with a central area of scarring.

pTN stage: pT1b N0

Lymph nodes, thoracic, level 4R, excision:

[page 3 of 3]
Reactive hyperplasia and scattered noncaseating granulomata.
Negative for malignancy, at least eight nodes.
Lymph nodes, thoracic, level 7, excision:
Reactive hyperplasia and scattered noncaseating granulomata.
Negative for malignancy, at least five nodes.

Comments

Several of the lymph nodes contain small noncaseating granulomas.
Two representative blocks from two separate specimens are each stained for acid fast bacilli and fungi. In the presence of appropriately staining positive and negative controls, both are negative. Clinical correlation is suggested, however.

The total number of lymph nodes stated (20) represents a conservative estimate, as the nature of the specimens submitted as number two, four and five do not permit an accurate counting of total lymph nodes.

At the request of the undersigned pathologist, these slides have been additionally reviewed by Dr. [REDACTED], who concurs with the diagnosis.

This report has been finalized at the [REDACTED] campus.

<Sign Out Dr. Signature>

Handwritten: 8/24/12

Source: NCI Genomic Data Commons file f871c186-6315-4bf7-8bc1-ae504066d5ff (TCGA-55-A4DG.E1EA2600-CEEE-4009-A2E7-D845153DB167.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).